Somatic mutation profile of tumor specimen TCGA-AO-A0J5-01A (aliquot TCGA-AO-A0J5-01A-11W-A050-09) from TCGA case TCGA-AO-A0J5, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 48.8 years (17,815 days).
Specimen TCGA-AO-A0J5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d4038c9-b069-4b89-8359-b4546aa974c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0J5-10A (Blood Derived Normal), aliquot TCGA-AO-A0J5-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45856a18-f98f-4b48-a145-19cbf03464d5

The open-access MAF lists 56 somatic variants for this specimen: 39 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 15, Nonsense Mutation 3, Frame Shift Ins 2, 3'UTR 1, RNA 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 31/109 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AACS | c.324C>G p.H108Q | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as COSV55536798; called by muse, mutect2, varscan2
- ACOT11 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 13/136 reads (10%) | catalogued as rs368544454; called by muse, mutect2, varscan2
- ATP10B | c.2212C>A p.L738I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV59151979; called by muse, mutect2, varscan2
- BIRC6 | c.7036T>A p.C2346S | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV70199340; called by muse, mutect2, varscan2
- CACNA1E | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 102/212 reads (48%) | catalogued as COSV62395163; called by muse, mutect2, varscan2
- COX4I2 | c.247+1G>A p.X83_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as COSV65781836; called by muse, mutect2, varscan2
- CSH2 | c.511A>C p.K171Q | Missense Mutation (SNP) | VAF 20/680 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV100400256; called by muse, mutect2
- CSMD2 | c.909C>G p.Y303* | Nonsense Mutation (SNP) | VAF 23/173 reads (13%) | catalogued as COSV53912932; called by muse, mutect2, varscan2
- CXCR3 | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV65461944; called by muse, mutect2, varscan2
- DOCK10 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51398988; called by muse, mutect2, varscan2
- DOCK5 | c.5007G>T p.R1669S | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.468); catalogued as COSV52402096; called by muse, mutect2, varscan2
- DOCK7 | c.2927C>T p.T976M (on ENST00000635253 / NM_001367561.1; = p.T945M on NM_033407.3) | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.27); catalogued as rs780945471, COSV99224919; called by muse, mutect2
- GATA3 | c.981_987dup p.R330Lfs*24 | Frame Shift Ins (INS) | VAF 30/125 reads (24%) | catalogued as COSV60516079; called by mutect2, varscan2
- GPR107 | c.1576C>A p.L526I (on ENST00000372406 / NM_001136557.2; = p.L478I on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV100714688; called by muse, mutect2
- GZMA | c.761T>C p.I254T | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99697051; called by muse, mutect2
- HDAC6 | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV61927350, COSV61928968; called by muse, mutect2, varscan2
- HIVEP1 | c.5461C>T p.P1821S | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV65101468; called by muse, mutect2, varscan2
- LCOR | c.4460C>T p.A1487V | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV53715944; called by muse, mutect2, varscan2
- LRRC7 | c.437C>T p.P146L (on ENST00000651989 / NM_001370785.2; = p.P113L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50459222; called by muse, mutect2, varscan2
- LRRC7 | c.3152G>C p.S1051T (on ENST00000651989 / NM_001370785.2; = p.S1018T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV50459458; called by muse, mutect2, varscan2
- LSM5 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs376563041; called by muse, mutect2, varscan2
- MAGEL2 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.046); catalogued as COSV58567229; called by muse, mutect2, varscan2
- MSN | c.1347C>T p.A449= | Splice Region (SNP) | VAF 106/689 reads (15%) | catalogued as COSV64304050; called by muse, mutect2, varscan2
- OXR1 | c.1958A>T p.E653V (on ENST00000442977 / NM_001198532.1; = p.E652V on NM_018002.3) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56329307; called by muse, mutect2, varscan2
- PHIP | c.4529G>A p.R1510Q | Missense Mutation (SNP) | VAF 21/376 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.388); catalogued as rs200729688, COSV99244390; called by muse, mutect2
- PPM1B | c.1242G>A p.M414I | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1332962357, COSV56766916; called by muse, mutect2, varscan2
- PREX2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774302685, COSV55749445; called by muse, mutect2, varscan2
- SETD5 | c.1079T>A p.V360E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56710219, COSV56711039; called by muse, mutect2
- SLC1A2 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 83/236 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1364953579, COSV53521470; called by muse, mutect2, varscan2
- SLC27A1 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV53097441; called by muse, mutect2, varscan2
- SMYD3 | c.656C>A p.P219H (on ENST00000490107 / NM_001375962.1; = p.P160H on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/250 reads (3%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.461); catalogued as COSV100830781; called by muse, mutect2
- TAS2R16 | c.831G>T p.M277I | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV50796893; called by muse, mutect2
- TMEM132D | c.2496G>T p.Q832H | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV67160459; called by muse, mutect2, varscan2
- TOM1 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV53334013; called by muse, mutect2, varscan2
- TSC22D1 | c.1849C>A p.P617T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV71775670; called by muse, mutect2, varscan2
- ZNF558 | c.515G>T p.R172I | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56862834; called by muse, mutect2
- ZNF831 | c.2794C>A p.L932M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.275); catalogued as COSV64040308; called by muse, mutect2, varscan2
- PSIP1 | c.158dup p.L53Ffs*13 | Frame Shift Ins (INS) | VAF 27/76 reads (36%) | called by mutect2, pindel, varscan2
- APOA4 | c.435G>A p.Q145= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100759349; called by muse, mutect2
- ATP10B | c.2211A>T p.T737= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV59151986; called by muse, mutect2, varscan2
- BRINP3 | c.1722T>C p.N574= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as COSV66524495; called by muse, mutect2, varscan2
- CLCN4 | c.1728C>T p.I576= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV66466555; called by muse, mutect2, varscan2
- FNDC1 | c.1326C>A p.G442= | Silent (SNP) | VAF 6/115 reads (5%) | catalogued as COSV99796121; called by muse, mutect2
- ITGA4 | c.465G>A p.K155= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs761009890, COSV52000305; called by muse, mutect2, varscan2
- LRRC66 | c.873C>T p.N291= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs771635095, COSV58634700; called by muse, mutect2
- MASP1 | c.726C>T p.C242= | Silent (SNP) | VAF 20/345 reads (6%) | catalogued as rs754845693, COSV99397302; called by muse, mutect2
- MLPH | c.1410A>G p.A470= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV52820532; called by muse, mutect2
- PDE3A | c.2442C>T p.Y814= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as rs1390457689, COSV62973003; called by muse, mutect2, varscan2
- PIWIL1 | c.573G>A p.V191= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as COSV55346802; called by muse, mutect2, varscan2
- PKDREJ | c.3495G>A p.V1165= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV99479076; called by muse, mutect2, varscan2
- SEC31B | c.3501G>A p.L1167= | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as rs1392049462, COSV59325351; called by muse, mutect2, varscan2
- SFTPA1 | c.276C>T p.G92= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as rs369292352; called by muse, mutect2
- TTC38 | c.465G>A p.L155= | Silent (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- MIR524 | n.79G>A | RNA (SNP) | VAF 28/178 reads (16%) | catalogued as rs770204898; called by muse, mutect2, varscan2
- NSMCE1 | c.*2C>T | 3'UTR (SNP) | VAF 31/100 reads (31%) | catalogued as COSV53732972; called by muse, mutect2, varscan2
